Somatic mutation profile of tumor specimen TCGA-AK-3456-01A (aliquot TCGA-AK-3456-01A-02D-1386-10) from TCGA case TCGA-AK-3456, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 48.8 years (17,821 days).
Specimen TCGA-AK-3456-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6ae896a-b390-4c9c-9a4c-6c1adcb8ab24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3456-10A (Blood Derived Normal), aliquot TCGA-AK-3456-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd1dabbe-9a65-4ece-8c47-96dc7c473602

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 20, Silent 11, Nonsense Mutation 1, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTSK | c.213T>A p.Y71* | Nonsense Mutation (SNP) | VAF 93/259 reads (36%) | catalogued as rs780202604, COSV55012890; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCD4 | c.503C>G p.P168R | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53993417, COSV53993704, COSV53993759; called by muse, mutect2
- ANK3 | c.9097G>C p.G3033R | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.457); catalogued as rs1206788662, COSV55069896, COSV99780324; called by muse, mutect2, varscan2
- ATP8A1 | c.2085C>T p.I695= | Splice Region (SNP) | VAF 88/253 reads (35%) | catalogued as rs772627948, COSV52541455; called by muse, mutect2, varscan2
- CARMIL2 | c.3860C>T p.A1287V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV54669017; called by muse, mutect2, varscan2
- CEP164 | c.2534G>A p.G845E | Missense Mutation (SNP) | VAF 102/264 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1348867402, COSV54043809; called by muse, mutect2, varscan2
- COBLL1 | c.1234C>T p.H412Y (on ENST00000392717; = p.H374Y on NM_014900.5) | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs149060063; called by muse, mutect2, varscan2
- DIO2 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV70445739; called by muse, mutect2, varscan2
- DUSP29 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148261941, COSV58301124; called by muse, mutect2
- FREM2 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.139); catalogued as COSV54844565; called by muse, mutect2
- HIVEP1 | c.3843G>C p.K1281N | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65103576; called by muse, mutect2, varscan2
- MCRS1 | c.842T>A p.F281Y | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV57791843; called by muse, mutect2, varscan2
- NDUFS1 | c.650A>C p.E217A | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51911574; called by muse, mutect2, varscan2
- NLRC5 | c.3539C>G p.P1180R | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV52659253; called by muse, mutect2
- NUCB1 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as COSV54387285; called by muse, mutect2, varscan2
- NYNRIN | c.5653G>A p.A1885T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.305); catalogued as COSV66843722; called by muse, mutect2, varscan2
- PCLO | c.10337A>G p.Q3446R | Missense Mutation (SNP) | VAF 127/411 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV61650417; called by muse, mutect2, varscan2
- PPP4R3A | c.1204C>G p.Q402E | Missense Mutation (SNP) | VAF 214/616 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.269); catalogued as COSV61505676; called by muse, mutect2, varscan2
- SLC9B2 | c.1610T>A p.V537D | Missense Mutation (SNP) | VAF 131/381 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV60020663; called by muse, mutect2, varscan2
- SQOR | c.507T>G p.N169K | Missense Mutation (SNP) | VAF 171/421 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV52942695; called by muse, mutect2, varscan2
- TAS1R3 | c.1639T>G p.S547A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.9); catalogued as COSV59564510; called by muse, varscan2
- ZNF215 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 111/322 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1371875367, COSV53494010; called by muse, mutect2, varscan2
- KRTAP10-9 | c.580_591del p.K194_C197del | In Frame Del (DEL) | VAF 36/145 reads (25%) | called by mutect2, pindel, varscan2
- PRAG1 | c.3042_3043insTT p.E1015Lfs*10 | Frame Shift Ins (INS) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- AARS2 | c.1281G>T p.G427= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs557359115, COSV55116481; called by muse, mutect2, varscan2
- CARD6 | c.696T>G p.V232= | Silent (SNP) | VAF 95/252 reads (38%) | catalogued as COSV54567571; called by muse, mutect2, varscan2
- COL27A1 | c.3225G>T p.G1075= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV61928759; called by muse, mutect2, varscan2
- ITPKC | c.1836C>T p.F612= | Silent (SNP) | VAF 70/235 reads (30%) | catalogued as COSV54572968, COSV54576158; called by muse, mutect2, varscan2
- KATNB1 | c.135C>T p.V45= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV65561082; called by muse, mutect2
- LOXL4 | c.6G>A p.A2= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs201076968, COSV53255316; called by muse, mutect2, varscan2
- NPTX2 | c.1044C>T p.G348= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs756266964, COSV55717138; called by muse, mutect2, varscan2
- PTGDR | c.1041C>T p.S347= | Silent (SNP) | VAF 149/356 reads (42%) | catalogued as COSV60094503; called by muse, mutect2, varscan2
- RRP12 | c.1095G>A p.E365= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV59669671; called by muse, mutect2, varscan2
- SCN11A | c.5019C>A p.P1673= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV56574152; called by muse, mutect2, varscan2
- SLC29A1 | c.177C>T p.D59= | Silent (SNP) | VAF 83/209 reads (40%) | catalogued as rs759661754, COSV57579457; called by muse, mutect2, varscan2
